Gene-level copy-number profile of tumor specimen TCGA-A2-A4S1-01A from TCGA case TCGA-A2-A4S1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Metaplastic carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.7 years (24,353 days).
Specimen TCGA-A2-A4S1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.fbe3afb5-4dcf-488b-b118-6c8adae6e740.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A4S1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a2406dd4-a60f-456d-9668-7bc7c205068d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 15,083; copy number 2: 16,740; copy number 3: 25,503; copy number 4: 2,154; copy number 5: 334; copy number 6: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A4S1-01A-21D-A25N-01): tumor purity 0.45, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15,047. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
